Gene-level copy-number profile of tumor specimen TCGA-2G-AAF2-01A from TCGA case TCGA-2G-AAF2, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 36.9 years (13,463 days).
Specimen TCGA-2G-AAF2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 54235e33-3736-4606-8897-45ad29a3080f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAF2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/5800e4f8-77a5-468b-af58-087fd05d9738

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,870; copy number 2: 19,449; copy number 3: 24,882; copy number 4: 10,509; copy number 5: 1,401; copy number 6: 749; copy number 7: 53; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 54 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,451,045–39,522,852, 1 gene, copy number 7: ADAM3A.
- chr11:4,287,499–4,288,083, 1 gene, copy number 10: SSU72P4.
- chr12:14,169,746–15,882,329, 38 genes, copy number 7: AC092470.1, AC135001.1, AC092112.1, MRPS18CP4, RNU6-491P, GNAI2P1, RPL30P11, ATF7IP, PLBD1, AC008114.1, RN7SKP134, PLBD1-AS1, GUCY2C, AC010168.1, AC010168.2, H4-16, H2AJ, WBP11, C12orf60, SMCO3, AC007655.2, ART4, AC007655.1, MGP, ERP27, ARHGDIB, PDE6H, LINC01489, RERG, RERG-IT1, RERG-AS1, METTL8P1, PTPRO, AC092183.1, EPS8, RNU6-251P, AC073651.1, AC073651.2.
- chr12:31,876,969–32,383,633, 14 genes, copy number 7 (within-gene range 5–7): LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1.

Autosomal genes at a single copy (total copy number 1): 1,358. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
